Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOF, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOF-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Seminoma NOS 9061/3
Site: (L) Testis NOS C62.9

Q 4/16/14

SURGICAL PATH [1]

Order Dr: _____

Order Clinic: _____

Order Dx: S/P EXCISION OF BIL. INGUINAL MASS

Specimen Source: L TESTICLE R INGUINA

CASE NO.: _____

GROSS EXAM DATE: _____

PHYSICIAN & PAGER #: _____

--- CONCLUSION/DIAGNOSTIC CODE -----

NON-ROUTINE

--- REPORT -----

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA WITH EXTENSIVE NECROSIS (10 CM), left testicle (A), orchiectomy. (see note)
2. SURGICAL MARGINS FREE OF TUMOR (A).
3. NO LYMPHOVASCULAR INVASION IDENTIFIED (A).
4. THERE IS NO INVASION OF EPIDIDYMIS (A).
5. UNINVOLVED TESTICULAR TISSUE NOT IDENTIFIED (A).
6. pT1NXMX (A).
7. TESTICLE WITH ADVANCED TUBULAR ATROPHY AND NO EVIDENCE OF SPERMATOGENESIS, right inguinal mass (B).
8. NODULAR HYPERPLASIA OF LEYDIG CELLS (B).

Note: The diagnosis of seminoma is confirmed by a positive c-kit and negative AE1/AE3 and CAM 5.2 stains and by the characteristic electron microscopic features

GROSS DESCRIPTION:

This case is received in two parts.

Part A is labeled with the patient's name, _____ and "left testicle." It consists of an apparent orchiectomy specimen that measures 10 x 8 x 6 cm and weighs 270 grams. The tunica vaginalis is smooth, glistening and pinkish in color. There is 1 cm long apparent spermatic cord attached with the specimen. The specimen is bivalved to reveal presence of a white, fleshy, homogenous tumor mass. On further sectioning through the mass, there is a hemorrhagic disreect

[page 2 of 2]
REPORT

area identified that measures 3 x 2 cm. This tumor mass seems to be replacing the entire testicular tissue. No recognizable normal testicular tissue seen. The tumor is not involving either the tunica vaginalis or the tunica albuginea, although it is approaching tunica albuginea on gross examination. No areas of necrosis were identified. Representative sections are taken as follows:

Cassette 1: Spermatic cord margin.
Cassette 2: Mid spermatic cord.
Cassette 3: Distal spermatic cord.
Cassette 4: Tumor with adjacent soft tissue at the superior margin.
Cassettes 5 and 6: Discrete red area seen on sectioning.
Cassettes 7 through 10: Representative sections through the tumor.

Part B of the same case was received fixed in formalin labeled with the patient's name, and "right inguinal mass." It consists of an oval soft tissue specimen that looks like a gonad. It measures 3.5 x 1.5 x 2 cm and has 5 x 3 x 1.5 cm fibroadipose tissue attached to it. The surface of this oval gonad type specimen is smooth, tan-gray and glistening. The specimen is inked, bivalved to reveal the presence of a discreet tan-brown homogenous cut surface which is encapsulated. No apparent spermatic cord could be identified with this specimen. On further sectioning, the specimen continued to show tan-brown homogenous cut surface without any other lesions. Representative sections are submitted in a total of six cassettes. R6.

Source: NCI Genomic Data Commons file 5f91fc74-c354-4395-bf66-02c88ee1e3e2 (TCGA-XE-AAOF.2815B0CC-441E-483C-96D1-4EFB9170CF75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).